Somatic mutation profile of tumor specimen HCM-SANG-0277-C18-01B (aliquot HCM-SANG-0277-C18-01B-01D-A79M-36) from HCMI case HCM-SANG-0277-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G3.
Specimen HCM-SANG-0277-C18-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f9f4f11-b821-4587-88b8-73cc787f2da9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0277-C18-10A (Blood Derived Normal), aliquot HCM-SANG-0277-C18-10A-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b9f8943a-343b-4c98-90f4-e6731cda9771

The open-access MAF lists 258 somatic variants for this specimen: 197 protein-altering or splice-affecting, 53 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 167, Silent 53, Nonsense Mutation 17, Frame Shift Del 5, Frame Shift Ins 5, Intron 2, 3'UTR 2, Nonstop Mutation 1, In Frame Del 1, RNA 1, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2995C>T p.Q999* | Nonsense Mutation (SNP) | VAF 74/336 reads (22%) | catalogued as rs75239284, CM994279, COSV57331655; ClinVar: pathogenic; called by muse, varscan2
- CPS1 | c.2359C>T p.R787* | Nonsense Mutation (SNP) | VAF 36/229 reads (16%) | catalogued as rs121912596, CM071660, COSV99243584; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MAP2K1 | c.361T>A p.C121S | Missense Mutation (SNP) | VAF 167/332 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1057519856, COSV100199074, COSV61068761; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CB | c.3151G>A p.E1051K | Missense Mutation (SNP) | VAF 188/425 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as COSV56683948; called by muse, mutect2, varscan2
- SMAD2 | c.1391C>G p.S464* | Nonsense Mutation (SNP) | VAF 35/212 reads (17%) | hotspot (GDC flag); catalogued as COSV50992836, COSV50992894, COSV50993280; called by muse, mutect2, varscan2
- A2ML1 | c.3647C>T p.A1216V | Missense Mutation (SNP) | VAF 50/243 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.584); catalogued as rs1041548414, COSV55285979; called by muse, mutect2, varscan2
- ABHD15 | c.1048G>A p.V350M | Missense Mutation (SNP) | VAF 129/557 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs374284598, COSV56196215; called by muse, mutect2, varscan2
- ANK3 | c.2980G>T p.G994W (on ENST00000280772 / NM_001320874.2; = p.G128W on NM_001149.3) | Missense Mutation (SNP) | VAF 84/369 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55055058; called by muse, mutect2, varscan2
- AP4M1 | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 112/416 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.406); catalogued as rs757649099, COSV57999393; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APC | c.4364del p.N1455Ifs*18 | Frame Shift Del (DEL) | VAF 62/358 reads (17%) | catalogued as CM080064, COSV57320740, COSV57379025; called by mutect2, pindel, varscan2
- ARMC4 | c.1006G>T p.A336S | Missense Mutation (SNP) | VAF 62/395 reads (16%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs749707046; called by muse, mutect2, varscan2
- ATP10A | c.2200T>G p.F734V | Missense Mutation (SNP) | VAF 99/448 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.759); catalogued as COSV63525890; called by muse, mutect2, varscan2
- BDNF | c.446C>T p.T149M | Missense Mutation (SNP) | VAF 74/392 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1339220115, COSV59234219; called by muse, mutect2, varscan2
- CCDC169 | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 52/385 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.648); catalogued as rs1289400696, COSV53484524; called by muse, mutect2, varscan2
- CELSR1 | c.5263G>A p.G1755S | Missense Mutation (SNP) | VAF 90/382 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.234); catalogued as rs745985122, COSV53087180, COSV53098535; called by muse, mutect2, varscan2
- CHCHD10 | c.226G>A p.G76R | Missense Mutation (SNP) | VAF 20/694 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs1246204510; called by muse, mutect2
- CSMD1 | c.748T>G p.F250V | Missense Mutation (SNP) | VAF 77/373 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV101227380; called by muse, mutect2, varscan2
- CTNS | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 64/317 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.238); catalogued as rs555311279, COSV50439978; called by muse, mutect2, varscan2
- CYP4F3 | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 40/180 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as rs753746588, COSV55408314; called by muse, mutect2
- DIO3 | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 138/430 reads (32%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs554569043, COSV63773161; called by muse, mutect2, varscan2
- DOCK3 | c.2236C>T p.R746* | Nonsense Mutation (SNP) | VAF 100/421 reads (24%) | catalogued as rs1030780615, COSV56553006; called by muse, mutect2, varscan2
- DOK6 | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 96/385 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.797); catalogued as rs1055076812, COSV66938476; called by muse, mutect2, varscan2
- DSG4 | c.784G>A p.V262I | Missense Mutation (SNP) | VAF 47/242 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.348); catalogued as rs776703259, COSV57391097; called by muse, mutect2, varscan2
- EFHC1 | c.1619C>T p.A540V | Missense Mutation (SNP) | VAF 127/552 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs769799699; called by muse, mutect2, varscan2
- EPPK1 | c.3700G>A p.E1234K | Missense Mutation (SNP) | VAF 125/614 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs782782070, COSV101599708; called by muse, mutect2, varscan2
- ERBB3 | c.2000G>T p.R667L | Missense Mutation (SNP) | VAF 123/447 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57247278, COSV57260257; called by muse, mutect2, varscan2
- EVC2 | c.2553G>A p.M851I | Missense Mutation (SNP) | VAF 60/336 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs545949431, COSV60388325; called by muse, mutect2, varscan2
- EVC2 | c.1349A>C p.K450T | Missense Mutation (SNP) | VAF 42/450 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV100185266; called by muse, mutect2
- FCRL4 | c.1288G>A p.A430T | Missense Mutation (SNP) | VAF 46/221 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs557969488, COSV54859731; called by muse, mutect2, varscan2
- FERD3L | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 190/627 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs768552326, COSV99285195; called by muse, mutect2, varscan2
- FOXC2 | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 18/640 reads (3%) | SIFT tolerated (0.31); PolyPhen benign (0.023); catalogued as rs1190156347, COSV100234306; called by muse, mutect2
- FPR2 | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 78/544 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs367971570; called by muse, mutect2, varscan2
- FSD1 | c.994C>T p.R332C | Missense Mutation (SNP) | VAF 73/337 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV55695912; called by muse, mutect2, varscan2
- FST | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 54/261 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs201163221; called by muse, mutect2, varscan2
- GABRA2 | c.1043G>C p.S348T | Missense Mutation (SNP) | VAF 22/405 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.186); catalogued as rs1293678055; called by muse, mutect2
- GPR174 | c.343C>T p.R115* | Nonsense Mutation (SNP) | VAF 113/252 reads (45%) | catalogued as rs753195995, COSV99338073; called by muse, mutect2, varscan2
- GRIN2A | c.1983A>C p.Q661H | Missense Mutation (SNP) | VAF 20/310 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV58022707; called by muse, mutect2
- GRIN2B | c.3508G>A p.G1170R | Missense Mutation (SNP) | VAF 62/570 reads (11%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.049); catalogued as COSV101663237; called by muse, mutect2
- GRM5 | c.3356C>T p.P1119L (on ENST00000305447 / NM_001143831.2; = p.P1087L on NM_000842.4) | Missense Mutation (SNP) | VAF 118/640 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV59595895, COSV59618119; called by muse, varscan2
- HK3 | c.976T>G p.L326V | Missense Mutation (SNP) | VAF 106/564 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as COSV99459770; called by muse, mutect2
- HRH4 | c.1091G>A p.R364H | Missense Mutation (SNP) | VAF 72/376 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs149820026; called by muse, mutect2, varscan2
- HS3ST3A1 | c.718G>A p.V240M | Missense Mutation (SNP) | VAF 75/662 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as rs1300016001; called by muse, mutect2, varscan2
- HS3ST3B1 | c.673G>A p.V225M | Missense Mutation (SNP) | VAF 25/362 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV100714485; called by muse, mutect2
- HSPG2 | c.362C>T p.S121L | Missense Mutation (SNP) | VAF 97/400 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs780963482, COSV65930185; called by muse, mutect2, varscan2
- IGKV1D-43 | c.155G>A p.S52N | Missense Mutation (SNP) | VAF 27/179 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as rs1415167798; called by muse, mutect2, varscan2
- KCNH8 | c.2380T>G p.L794V | Missense Mutation (SNP) | VAF 16/432 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.148); catalogued as rs1200200106, COSV60460214, COSV60478079; called by muse, mutect2
- KCNQ2 | c.1657C>T p.R553W (on ENST00000359125 / NM_172107.4; = p.R525W on NM_004518.6) | Missense Mutation (SNP) | VAF 63/305 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759584387, CM136425; ClinVar: pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- KLHL10 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 100/409 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs782626896; called by muse, mutect2, varscan2
- LOXL4 | c.553G>A p.G185S | Missense Mutation (SNP) | VAF 117/475 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1459020336; called by muse, mutect2, varscan2
- MAP2K3 | c.743A>C p.K248T (on ENST00000342679 / NM_145109.3; = p.K219T on NM_002756.4) | Missense Mutation (SNP) | VAF 27/632 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1229469947; called by muse, mutect2
- MKS1 | c.1543C>T p.R515C | Missense Mutation (SNP) | VAF 54/285 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as rs775558298; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH6 | c.2363C>T p.T788M | Missense Mutation (SNP) | VAF 93/452 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as rs746758304; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO9A | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 24/496 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1297349712, COSV61853222; called by muse, mutect2
- MYOM2 | c.2132C>T p.P711L | Missense Mutation (SNP) | VAF 14/419 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750124935; called by muse, mutect2
- NME8 | c.507dup p.V170Sfs*5 | Frame Shift Ins (INS) | VAF 21/204 reads (10%) | catalogued as rs1167912395; called by mutect2, pindel, varscan2
- NTRK1 | c.1145C>A p.P382H | Missense Mutation (SNP) | VAF 104/433 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs763940977; called by muse, mutect2, varscan2
- OR4C46 | c.101T>G p.I34S | Missense Mutation (SNP) | VAF 17/440 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV60221282; called by muse, mutect2
- OR56B1 | c.704T>G p.L235R | Missense Mutation (SNP) | VAF 19/419 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100402645; called by muse, mutect2
- OR6Y1 | c.899A>G p.H300R | Missense Mutation (SNP) | VAF 39/221 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1200239720; called by muse, mutect2, varscan2
- OR8H3 | c.187T>G p.F63V | Missense Mutation (SNP) | VAF 15/479 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57907444; called by muse, mutect2
- PCDHA8 | c.1919C>T p.A640V | Missense Mutation (SNP) | VAF 114/460 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.022); catalogued as rs782601520, COSV65329548, COSV65330942; called by muse, mutect2, varscan2
- PCDHB3 | c.1466C>T p.S489L | Missense Mutation (SNP) | VAF 42/825 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.927); catalogued as COSV50564466; called by muse, mutect2
- PCDHGA5 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 45/320 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.177); catalogued as COSV54014928; called by muse, mutect2, varscan2
- PGLYRP1 | c.313G>A p.V105I | Missense Mutation (SNP) | VAF 68/536 reads (13%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.481); catalogued as rs573916071, COSV99151501; called by muse, mutect2, varscan2
- PIK3CB | c.1661A>G p.E554G | Missense Mutation (SNP) | VAF 163/357 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56689383; called by muse, mutect2, varscan2
- PKHD1 | c.9824T>G p.L3275R | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV100582291, COSV61862672; called by muse, mutect2
- PLPPR4 | c.1561A>G p.R521G | Missense Mutation (SNP) | VAF 19/355 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV64564975, COSV64566071; called by muse, mutect2
- PPP1R3A | c.1129A>G p.S377G | Missense Mutation (SNP) | VAF 72/414 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as COSV52888854; called by muse, mutect2, varscan2
- PRAG1 | c.4001G>A p.R1334H | Missense Mutation (SNP) | VAF 34/622 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as rs1444999069; called by muse, mutect2
- PTX3 | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 64/381 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as rs750633744; called by muse, mutect2, varscan2
- RBM47 | c.1046G>A p.C349Y | Missense Mutation (SNP) | VAF 18/601 reads (3%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as COSV55931642; called by muse, mutect2
- RFLNB | c.154G>A p.V52M | Missense Mutation (SNP) | VAF 60/375 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs782557368; called by muse, mutect2, varscan2
- RGS11 | c.940C>T p.R314W (on ENST00000397770 / NM_183337.3; = p.R293W on NM_003834.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/341 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs747085732, COSV51452388; called by muse, mutect2, varscan2
- RMND5B | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 50/273 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs574041577; called by muse, mutect2, varscan2
- RNFT2 | c.925C>T p.R309* | Nonsense Mutation (SNP) | VAF 80/377 reads (21%) | catalogued as rs752308240; called by muse, mutect2, varscan2
- ROBO2 | c.1918C>T p.R640C | Missense Mutation (SNP) | VAF 65/311 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs763833545, COSV59905182; called by muse, varscan2
- RYR1 | c.5171G>A p.R1724H | Missense Mutation (SNP) | VAF 143/917 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.948); catalogued as rs372800648; called by muse, mutect2, varscan2
- SH3BP5 | c.992C>T p.P331L | Missense Mutation (SNP) | VAF 82/414 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.578); catalogued as rs772857315; called by muse, mutect2, varscan2
- SHOC1 | c.2173G>A p.E725K | Missense Mutation (SNP) | VAF 60/310 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as rs889292600, COSV100598079; called by muse, mutect2, varscan2
- SHPK | c.377C>T p.T126M | Missense Mutation (SNP) | VAF 115/509 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs772517886; called by muse, mutect2, varscan2
- SKIV2L | c.3605G>A p.R1202H | Missense Mutation (SNP) | VAF 28/826 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs368453711; called by muse, mutect2
- SLC8A1 | c.167A>C p.K56T | Missense Mutation (SNP) | VAF 26/492 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV60479849; called by muse, mutect2
- SNED1 | c.2065G>A p.G689R | Missense Mutation (SNP) | VAF 91/422 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as rs565535804; called by muse, mutect2, varscan2
- SORCS3 | c.1055C>T p.A352V | Missense Mutation (SNP) | VAF 60/320 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.136); catalogued as rs550554404, COSV63804214; called by muse, mutect2, varscan2
- SPG11 | c.3532C>T p.H1178Y | Missense Mutation (SNP) | VAF 50/204 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as rs1396440197; called by muse, mutect2, varscan2
- TRANK1 | c.7813C>T p.R2605W | Missense Mutation (SNP) | VAF 85/467 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs371549764; called by muse, varscan2
- TRIM49 | c.979A>C p.S327R | Missense Mutation (SNP) | VAF 54/404 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as COSV61670608; called by muse, varscan2
- TRIM58 | c.501G>T p.K167N | Missense Mutation (SNP) | VAF 41/262 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs755932300, COSV100824884, COSV63571084; called by muse, mutect2, varscan2
- TRIM67 | c.1171G>A p.V391I | Missense Mutation (SNP) | VAF 69/288 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.781); catalogued as rs759061291, COSV64157994; called by muse, mutect2, varscan2
- TRIML2 | c.650A>T p.K217M | Missense Mutation (SNP) | VAF 38/350 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as COSV58719574; called by muse, mutect2, varscan2
- TTN | c.12250C>T p.R4084W (on ENST00000591111; = p.R4038W on NM_003319.4) | Missense Mutation (SNP) | VAF 81/354 reads (23%) | catalogued as rs1265208597, COSV59867986, COSV60391908; called by muse, mutect2, varscan2
- TTN | c.1799A>T p.K600M | Missense Mutation (SNP) | VAF 37/205 reads (18%) | PolyPhen benign (0.244); catalogued as rs750819553; called by muse, mutect2, varscan2
- UBE2J2 | c.159G>A p.M53I | Missense Mutation (SNP) | VAF 59/259 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV59573782; called by muse, mutect2, varscan2
- VSX1 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 146/734 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.041); catalogued as rs746221110; called by muse, mutect2, varscan2
- YIPF7 | c.670T>C p.F224L | Missense Mutation (SNP) | VAF 9/292 reads (3%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV60657468; called by muse, mutect2
- ZFP69 | c.1534C>T p.R512* | Nonsense Mutation (SNP) | VAF 57/275 reads (21%) | catalogued as rs200916688; called by muse, mutect2, varscan2
- ZNF175 | c.610A>C p.S204R | Missense Mutation (SNP) | VAF 36/454 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV99219729; called by muse, mutect2
- ZNF33A | c.1348C>T p.R450C (on ENST00000458705 / NM_006974.3; = p.R451C on NM_006954.2) | Missense Mutation (SNP) | VAF 64/303 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs374444658; called by muse, mutect2, varscan2
- ZNF613 | c.586C>T p.R196* (on ENST00000293471 / NM_001031721.4; = p.R160* on NM_024840.4) | Nonsense Mutation (SNP) | VAF 71/483 reads (15%) | catalogued as rs752784535, COSV53271265; called by muse, mutect2, varscan2
- ZNF681 | c.704G>C p.C235S | Missense Mutation (SNP) | VAF 33/518 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV101267476; called by muse, mutect2
- ZNF93 | c.886C>G p.Q296E | Missense Mutation (SNP) | VAF 30/211 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.182); catalogued as COSV100652171; called by muse, mutect2, varscan2
- ZSCAN18 | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 90/645 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1555800718, COSV53733122, COSV99559346; called by muse, mutect2, varscan2
- ADAMTS16 | c.734del p.K245Sfs*38 | Frame Shift Del (DEL) | VAF 65/291 reads (22%) | called by mutect2, pindel, varscan2
- AKAP12 | c.2602dup p.S868Kfs*12 | Frame Shift Ins (INS) | VAF 81/361 reads (22%) | called by mutect2, varscan2
- AMH | c.1676G>T p.C559F | Missense Mutation (SNP) | VAF 99/549 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKRD62 | c.1756G>T p.E586* | Nonsense Mutation (SNP) | VAF 39/255 reads (15%) | called by muse, mutect2, varscan2
- ANXA9 | c.137A>T p.D46V | Missense Mutation (SNP) | VAF 82/401 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CDH13 | c.324A>C p.E108D | Missense Mutation (SNP) | VAF 50/297 reads (17%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- CFAP299 | c.651A>C p.E217D | Missense Mutation (SNP) | VAF 24/368 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CHST8 | c.646G>T p.A216S | Missense Mutation (SNP) | VAF 64/812 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- CNTN4 | c.2599T>G p.L867V | Missense Mutation (SNP) | VAF 70/408 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- CRACR2B | c.1045C>T p.R349W (on ENST00000525077 / NM_001286606.2; = p.A293V on NM_173584.4) | Missense Mutation (SNP) | VAF 95/476 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- CTNND1 | c.2479C>T p.Q827* (on ENST00000399050 / NM_001085458.2; = p.Q821* on NM_001331.3) | Nonsense Mutation (SNP) | VAF 55/243 reads (23%) | called by muse, mutect2, varscan2
- CYLC1 | c.1406A>C p.K469T | Missense Mutation (SNP) | VAF 17/228 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.919); called by muse, mutect2
- DCAF12L2 | c.1239A>C p.Q413H | Missense Mutation (SNP) | VAF 51/321 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DMBT1 | c.3266G>A p.G1089D (on ENST00000338354 / NM_001377530.1; = p.G590D on NM_004406.3) | Missense Mutation (SNP) | VAF 60/283 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH7 | c.5251T>G p.Y1751D | Missense Mutation (SNP) | VAF 28/274 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- E2F2 | c.128C>T p.T43I | Missense Mutation (SNP) | VAF 134/671 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- EDA2R | c.516T>C p.R172= | Splice Region (SNP) | VAF 10/153 reads (7%) | called by muse, mutect2
- FST | c.765dup p.C256Mfs*16 | Frame Shift Ins (INS) | VAF 67/293 reads (23%) | called by mutect2, pindel, varscan2
- GAS2L3 | c.1325_1326insA p.K443Qfs*22 | Frame Shift Ins (INS) | VAF 60/354 reads (17%) | called by mutect2, pindel, varscan2
- GDF1 | c.193C>A p.L65M | Missense Mutation (SNP) | VAF 146/647 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GGN | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 185/1085 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GPR141 | c.172T>G p.L58V | Missense Mutation (SNP) | VAF 40/596 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- GRAMD1C | c.1499T>A p.I500N | Missense Mutation (SNP) | VAF 18/356 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.289); called by muse, mutect2
- H3C10 | c.112_114del p.K38del | In Frame Del (DEL) | VAF 69/367 reads (19%) | called by pindel, varscan2
- HPN | c.761A>G p.N254S | Missense Mutation (SNP) | VAF 349/735 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- KCNA10 | c.1304A>G p.K435R | Missense Mutation (SNP) | VAF 42/458 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- KCNH4 | c.1139G>A p.W380* | Nonsense Mutation (SNP) | VAF 110/449 reads (24%) | called by muse, mutect2, varscan2
- KIAA0895L | c.923T>A p.L308Q | Missense Mutation (SNP) | VAF 152/606 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIF15 | c.3496G>A p.G1166R | Missense Mutation (SNP) | VAF 98/399 reads (25%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF16B | c.1262A>C p.E421A | Missense Mutation (SNP) | VAF 44/270 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- KMT2B | c.3805G>T p.E1269* | Nonsense Mutation (SNP) | VAF 273/597 reads (46%) | called by muse, mutect2, varscan2
- KRT34 | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 36/420 reads (9%) | called by muse, mutect2
- LAMA4 | c.2012_2013dup p.L672Tfs*32 (on ENST00000230538 / NM_001105206.3; = p.L665Tfs*32 on NM_002290.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 40/428 reads (9%) | called by mutect2, pindel
- LBH | c.194T>G p.V65G | Missense Mutation (SNP) | VAF 46/476 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- LRRC49 | c.1390A>C p.K464Q | Missense Mutation (SNP) | VAF 90/184 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- MAP7D1 | c.55G>T p.A19S | Missense Mutation (SNP) | VAF 54/228 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MGAM2 | c.5377A>G p.T1793A | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.481); called by muse, mutect2
- MKRN3 | c.62A>C p.E21A | Missense Mutation (SNP) | VAF 20/494 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.026); called by muse, mutect2
- MLNR | c.28G>A p.G10S | Missense Mutation (SNP) | VAF 90/411 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MSH5 | c.2231T>C p.V744A | Missense Mutation (SNP) | VAF 65/343 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- MYH8 | c.3553A>G p.T1185A | Missense Mutation (SNP) | VAF 51/257 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- NEURL1B | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 69/374 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NMUR2 | c.547A>T p.S183C | Missense Mutation (SNP) | VAF 35/418 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2
- NPR1 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 75/450 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- NXF1 | c.849G>C p.M283I | Missense Mutation (SNP) | VAF 108/423 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OR1J2 | c.845C>A p.T282K | Missense Mutation (SNP) | VAF 52/279 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- OR2AT4 | c.49T>C p.Y17H | Missense Mutation (SNP) | VAF 82/416 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- OR2J2 | c.818A>C p.K273T | Missense Mutation (SNP) | VAF 32/400 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); called by muse, mutect2
- OR2T8 | c.191T>C p.L64P | Missense Mutation (SNP) | VAF 48/644 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.216); called by muse, mutect2
- OR9H1P | c.698A>G p.*233Wext*? | Nonstop Mutation (SNP) | VAF 48/312 reads (15%) | called by muse, mutect2, varscan2
- OTUD7A | c.1189G>A p.D397N (on ENST00000307050 / NM_001382637.1; = p.D390N on NM_130901.3) | Missense Mutation (SNP) | VAF 39/363 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- P4HA2 | c.1065G>T p.E355D | Missense Mutation (SNP) | VAF 39/222 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCDHB1 | c.1931T>G p.L644R | Missense Mutation (SNP) | VAF 43/493 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2
- PCF11 | c.1194C>A p.N398K | Missense Mutation (SNP) | VAF 54/271 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PKIA | c.199G>T p.A67S | Missense Mutation (SNP) | VAF 72/312 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLEKHB1 | c.485G>A p.R162K | Missense Mutation (SNP) | VAF 83/341 reads (24%) | SIFT tolerated (0.98); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- PPFIA2 | c.2595A>T p.L865F | Missense Mutation (SNP) | VAF 58/275 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- PRDM1 | c.437A>C p.H146P | Missense Mutation (SNP) | VAF 47/334 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PTPN13 | c.1417T>G p.L473V | Missense Mutation (SNP) | VAF 25/279 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2
- RBM39 | c.1181_1182del p.S394Ffs*14 | Frame Shift Del (DEL) | VAF 63/326 reads (19%) | called by pindel, varscan2
- RGL4 | c.1038A>C p.K346N | Missense Mutation (SNP) | VAF 24/183 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- RHOA | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 44/221 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- RNF111 | c.1927C>T p.R643* | Nonsense Mutation (SNP) | VAF 126/298 reads (42%) | called by muse, mutect2, varscan2
- RNF152 | c.359G>T p.R120L | Missense Mutation (SNP) | VAF 99/400 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- SAC3D1 | c.583G>C p.E195Q | Missense Mutation (SNP) | VAF 29/415 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.247); called by muse, mutect2
- SCN7A | c.1831C>G p.P611A | Missense Mutation (SNP) | VAF 43/216 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- SETBP1 | c.3043T>A p.S1015T | Missense Mutation (SNP) | VAF 99/400 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- SKIDA1 | c.2146G>A p.G716S | Missense Mutation (SNP) | VAF 78/330 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- SKOR2 | c.2681A>C p.K894T (on ENST00000425639 / NM_001278063.4; = p.R260= on NM_001037802.3) | Missense Mutation (SNP) | VAF 18/266 reads (7%) | SIFT deleterious, low confidence (0.01); called by muse, mutect2
- SLC39A3 | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 101/445 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- SLC4A2 | c.1943C>G p.A648G | Missense Mutation (SNP) | VAF 114/394 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMAD2 | c.439G>T p.E147* | Nonsense Mutation (SNP) | VAF 76/349 reads (22%) | called by muse, mutect2, varscan2
- SOX9 | c.1161_1173del p.E388Pfs*11 | Frame Shift Del (DEL) | VAF 119/636 reads (19%) | called by mutect2, pindel, varscan2
- ST8SIA6 | c.104T>G p.I35S | Missense Mutation (SNP) | VAF 34/341 reads (10%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- STRN | c.1673del p.P558Lfs*9 | Frame Shift Del (DEL) | VAF 46/205 reads (22%) | called by mutect2, pindel, varscan2
- SVEP1 | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 90/499 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- TBXA2R | c.971G>A p.S324N | Missense Mutation (SNP) | VAF 154/591 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- TIMP3 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 81/299 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- TSPY1 | c.597C>A p.C199* | Nonsense Mutation (SNP) | VAF 43/772 reads (6%) | called by muse, mutect2
- TTLL12 | c.1669G>T p.E557* | Nonsense Mutation (SNP) | VAF 74/352 reads (21%) | called by muse, mutect2, varscan2
- UBR2 | c.2973G>T p.W991C | Missense Mutation (SNP) | VAF 57/285 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UNC79 | c.3287T>G p.F1096C (on ENST00000393151 / NM_001346218.2; = p.F919C on NM_020818.5) | Missense Mutation (SNP) | VAF 62/772 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- UTF1 | c.986C>T p.A329V | Missense Mutation (SNP) | VAF 106/498 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- WASF3 | c.1360C>A p.L454M | Missense Mutation (SNP) | VAF 46/273 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WDFY4 | c.3764T>G p.L1255R | Missense Mutation (SNP) | VAF 30/290 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- XYLB | c.53A>G p.Q18R | Missense Mutation (SNP) | VAF 22/560 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2
- ZIK1 | c.162A>T p.E54D | Missense Mutation (SNP) | VAF 43/735 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZNF345 | c.834A>T p.R278S | Missense Mutation (SNP) | VAF 65/534 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- ZNF430 | c.736T>G p.S246A | Missense Mutation (SNP) | VAF 11/294 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.339); called by muse, mutect2
- ZNF461 | c.920G>C p.G307A | Missense Mutation (SNP) | VAF 74/596 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ZNF492 | c.647A>T p.K216M | Missense Mutation (SNP) | VAF 41/282 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF677 | c.673T>C p.S225P | Missense Mutation (SNP) | VAF 18/506 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2
- ZNF682 | c.551C>A p.S184Y | Missense Mutation (SNP) | VAF 51/321 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- ZNF85 | c.1437G>C p.E479D | Missense Mutation (SNP) | VAF 37/217 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- ZNF850 | c.1908A>C p.Q636H | Missense Mutation (SNP) | VAF 20/744 reads (3%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2
- ACKR1 | c.346T>C p.L116= | Silent (SNP) | VAF 22/644 reads (3%) | called by muse, mutect2
- ADAD2 | c.741G>A p.P247= (on ENST00000315906 / NM_001145400.2; = p.P329= on NM_139174.4) | Silent (SNP) | VAF 93/462 reads (20%) | catalogued as rs374108586; called by muse, mutect2, varscan2
- ADAMTS16 | c.1779T>G p.S593= | Silent (SNP) | VAF 16/460 reads (3%) | catalogued as COSV56991849; called by muse, mutect2
- ADARB2 | c.82C>A p.R28= | Silent (SNP) | VAF 52/331 reads (16%) | catalogued as rs1334103357, COSV67240031; called by muse, mutect2, varscan2
- ASCL1 | c.447G>A p.A149= | Silent (SNP) | VAF 19/644 reads (3%) | catalogued as COSV57150769; called by muse, mutect2
- BARHL2 | c.189T>G p.S63= | Silent (SNP) | VAF 31/709 reads (4%) | catalogued as COSV64980924; called by muse, mutect2
- BNC2 | c.243C>T p.F81= | Silent (SNP) | VAF 77/478 reads (16%) | catalogued as rs754849003, COSV66140591; called by muse, mutect2, varscan2
- CDH10 | c.1569A>G p.K523= | Silent (SNP) | VAF 16/299 reads (5%) | catalogued as COSV52580120; called by muse, mutect2
- CDH26 | c.1320C>T p.S440= | Silent (SNP) | VAF 65/358 reads (18%) | catalogued as rs747859766; called by muse, mutect2, varscan2
- CRB2 | c.576G>A p.P192= | Silent (SNP) | VAF 50/498 reads (10%) | catalogued as rs1040869162; called by muse, mutect2, varscan2
- CSMD1 | c.3717T>G p.T1239= (on ENST00000520002; = p.T1238= on NM_033225.6) | Silent (SNP) | VAF 86/380 reads (23%) | catalogued as COSV59310134; called by muse, mutect2, varscan2
- CSMD3 | c.3045A>T p.I1015= (on ENST00000297405 / NM_001363185.1; = p.I911= on NM_052900.3) | Silent (SNP) | VAF 10/295 reads (3%) | called by muse, mutect2
- DNAH5 | c.8004A>G p.G2668= | Silent (SNP) | VAF 52/238 reads (22%) | called by muse, mutect2
- DSEL | c.3459C>T p.A1153= | Silent (SNP) | VAF 120/495 reads (24%) | called by muse, mutect2, varscan2
- FAM20C | c.615G>A p.A205= | Silent (SNP) | VAF 108/497 reads (22%) | catalogued as rs767807372, COSV58233063; called by muse, mutect2, varscan2
- FLI1 | c.462C>T p.I154= | Silent (SNP) | VAF 63/417 reads (15%) | catalogued as rs745359490, COSV55644091; called by muse, mutect2, varscan2
- FREM2 | c.1402T>C p.L468= | Silent (SNP) | VAF 24/478 reads (5%) | catalogued as COSV54826828, COSV54842467; called by muse, mutect2
- FXYD5 | c.318G>A p.T106= | Silent (SNP) | VAF 365/714 reads (51%) | catalogued as rs373475541; called by muse, mutect2, varscan2
- GABBR1 | c.2877T>C p.L959= | Silent (SNP) | VAF 28/367 reads (8%) | called by muse, mutect2
- GK3P | c.738G>A p.G246= | Silent (SNP) | VAF 77/379 reads (20%) | catalogued as rs756937320, COSV56983892; called by muse, mutect2, varscan2
- GNAO1 | c.450C>T p.N150= | Silent (SNP) | VAF 75/272 reads (28%) | catalogued as rs185369495; ClinVar: benign; called by muse, mutect2, varscan2
- GPR26 | c.189G>A p.T63= | Silent (SNP) | VAF 68/712 reads (10%) | catalogued as rs776487078, COSV52932599; called by muse, mutect2
- HRNR | c.2001C>T p.S667= | Silent (SNP) | VAF 113/589 reads (19%) | catalogued as rs374849852; called by muse, mutect2, varscan2
- JHY | c.1980C>T p.L660= | Silent (SNP) | VAF 60/226 reads (27%) | catalogued as rs1340407392, COSV57077891, COSV57079963; called by muse, mutect2, varscan2
- KIF26B | c.3769T>C p.L1257= | Silent (SNP) | VAF 20/808 reads (2%) | called by muse, mutect2
- KLF7 | c.60C>A p.G20= | Silent (SNP) | VAF 92/414 reads (22%) | called by muse, mutect2, varscan2
- KLHL20 | c.282A>G p.R94= | Silent (SNP) | VAF 36/486 reads (7%) | called by muse, mutect2
- LCE6A | c.162T>A p.P54= | Silent (SNP) | VAF 70/325 reads (22%) | called by muse, mutect2, varscan2
- LCN6 | c.279C>T p.S93= | Silent (SNP) | VAF 130/463 reads (28%) | catalogued as rs148747287; called by muse, mutect2, varscan2
- LRRC4B | c.1905G>A p.A635= | Silent (SNP) | VAF 146/1223 reads (12%) | catalogued as rs767664857; called by muse, mutect2, varscan2
- MUC16 | c.1317A>G p.P439= | Silent (SNP) | VAF 14/446 reads (3%) | called by muse, mutect2
- NIPBL | c.2856G>A p.A952= | Silent (SNP) | VAF 40/311 reads (13%) | catalogued as rs371566938; ClinVar: likely benign; called by muse, mutect2, varscan2
- NUDT6 | c.678C>T p.I226= | Silent (SNP) | VAF 69/354 reads (19%) | called by muse, mutect2, varscan2
- OBSL1 | c.4023C>T p.C1341= | Silent (SNP) | VAF 106/461 reads (23%) | catalogued as rs749717075, COSV54708751; ClinVar: uncertain significance; called by muse, varscan2
- OR2M7 | c.391A>C p.R131= | Silent (SNP) | VAF 24/394 reads (6%) | catalogued as COSV100522763; called by muse, mutect2
- PAX6 | c.420C>T p.D140= | Silent (SNP) | VAF 88/463 reads (19%) | catalogued as rs1800427; called by muse, mutect2, varscan2
- PCDHA13 | c.2229C>T p.S743= | Silent (SNP) | VAF 59/282 reads (21%) | catalogued as COSV56494255; called by muse, mutect2, varscan2
- PCDHGA5 | c.990C>T p.S330= | Silent (SNP) | VAF 106/464 reads (23%) | catalogued as COSV54049695; called by muse, mutect2, varscan2
- PDGFB | c.366G>A p.P122= | Silent (SNP) | VAF 110/471 reads (23%) | catalogued as rs772178312; called by muse, mutect2, varscan2
- PEG3 | c.4578T>C p.T1526= | Silent (SNP) | VAF 21/563 reads (4%) | catalogued as COSV55626937, COSV55641370; called by muse, mutect2
- PEG3 | c.651T>A p.A217= | Silent (SNP) | VAF 32/484 reads (7%) | called by muse, mutect2
- POU4F1 | c.999C>T p.L333= | Silent (SNP) | VAF 83/412 reads (20%) | catalogued as rs200023415, COSV65884467, COSV65884714, COSV65885282; called by muse, mutect2, varscan2
- SIGLEC5 | c.612C>T p.P204= | Silent (SNP) | VAF 127/901 reads (14%) | called by muse, mutect2, varscan2
- SLCO1A2 | c.429G>A p.T143= | Silent (SNP) | VAF 62/285 reads (22%) | catalogued as rs1486008663; called by muse, mutect2, varscan2
- SLF1 | c.81T>G p.L27= | Silent (SNP) | VAF 39/189 reads (21%) | called by muse, mutect2, varscan2
- SLITRK4 | c.531C>T p.F177= | Silent (SNP) | VAF 83/195 reads (43%) | catalogued as rs143940780, COSV62022415; called by muse, mutect2, varscan2
- STX19 | c.807A>G p.G269= | Silent (SNP) | VAF 68/316 reads (22%) | called by muse, mutect2, varscan2
- THBD | c.1095C>T p.P365= | Silent (SNP) | VAF 17/573 reads (3%) | called by muse, mutect2
- TSC2 | c.669C>T p.D223= | Silent (SNP) | VAF 52/248 reads (21%) | catalogued as rs35501344; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- TUBB4A | c.1281C>T p.D427= | Silent (SNP) | VAF 102/454 reads (22%) | catalogued as rs149205820; called by muse, mutect2, varscan2
- ZNF430 | c.303G>A p.A101= | Silent (SNP) | VAF 52/269 reads (19%) | catalogued as rs147302415; called by muse, mutect2, varscan2
- ZNF566 | c.666T>G p.T222= | Silent (SNP) | VAF 26/626 reads (4%) | called by muse, mutect2
- ZNF831 | c.822C>T p.A274= | Silent (SNP) | VAF 98/482 reads (20%) | catalogued as COSV64043031; called by muse, mutect2, varscan2
- AC244258.1 | n.436G>A | RNA (SNP) | VAF 60/218 reads (28%) | called by muse, mutect2, varscan2
- CHST9 | chr18:26915010 T>G | 3'Flank (SNP) | VAF 21/259 reads (8%) | called by muse, mutect2
- CPLANE1 | c.*1338T>G | 3'UTR (SNP) | VAF 56/303 reads (18%) | called by muse, mutect2, varscan2
- LAMP2 | c.*2818T>C | 3'UTR (SNP) | VAF 60/145 reads (41%) | catalogued as COSV52352034; called by muse, mutect2, varscan2
- MARCHF1 | c.242+365A>C | Intron (SNP) | VAF 14/370 reads (4%) | catalogued as COSV99920126; called by muse, mutect2
- UMOD | c.-121T>A | 5'UTR (SNP) | VAF 56/309 reads (18%) | called by muse, mutect2, varscan2
- VIPR2 | c.51+320C>T | Intron (SNP) | VAF 31/770 reads (4%) | called by muse, mutect2
- Z99774.2 | chr22:26668175 G>A | 5'Flank (SNP) | VAF 64/234 reads (27%) | catalogued as rs928160133; called by muse, varscan2
